TCGA case TCGA-44-6776 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2a1de2e-6451-4c95-8ce6-263f2b7e6eff

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,150 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Synchronous primary (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,938 days (5.3 years); Disease response: Tumor Free.
- Days to follow up: 2,616 days (7.2 years); Disease response: Tumor Free.

Other clinical attributes
- DLCO (% of predicted): 80; FEV1/FVC after bronchodilator (%): 85; FEV1/FVC before bronchodilator (%): 95; FEV1 after bronchodilator (% of reference): 82; FEV1 before bronchodilator (% of reference): 74.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 45; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 2005.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-6776-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-44-6776-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-44-6776-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-44-6776-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-6776-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-6776-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Pulmonary function test indicator: Yes.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lymphoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous lymphoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,616 days; disease-specific survival: no event (censored), 2,616 days; disease-free interval: no event (censored), 2,616 days; progression-free interval: no event (censored), 2,616 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-6776-01A-11D-1854-01): tumor purity 0.65, ploidy 1.95, whole-genome doublings 0.
